Surgical pathology report (de-identified scan), TCGA case TCGA-CV-6933, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-6933-01A (Primary Tumor).

[page 1 of 2]
DIAGNOSIS

- (A) DISTAL MOST FACIAL MARGIN NERVE, BIOPSY:
Peripheral nerve, no tumor present.
- (B) PROXIMAL NEUROVASCULAR BUNDLE V3, BIOPSY:
Skeletal muscle and vessels, no tumor present.
- (C) TEETH, OBSTRUCTION:
Teeth, gross diagnosis only.
- (D) GLOSSECTOMY, PARTIAL MANDIBULECTOMY, MAXILLECTOMY, AND LEFT FUNCTIONAL
NECK DISSECTION, RESECTION:
INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CARCINOMA OF TONGUE
CARCINOMA INVOLVES DEEP SOFT TISSUE.
ANGIOLYMPHATIC AND PERINEURAL INVASION ARE IDENTIFIED.
Surgical margins of resection, no tumor present.
METASTATIC SQUAMOUS CARCINOMA IN 1 OF 32 LEFT NECK LYMPH NODES.
Submandibular gland, no tumor present.

SIGNATURE:

ENTIRE REPORT ELECTRONICALLY SIGNED BY:

GROSS DESCRIPTION

(A) DISTAL MOST FACIAL MARGIN NERVE - Two fragments of red and white soft tissue (0.5 x 0.4 x 0.2 cm) in aggregate. Submitted entirely for frozen section, A.

*FS/DX: PERIPHERAL NERVE, NO TUMOR PRESENT.

(B) PROXIMAL NEUROVASCULAR BUNDLE V 3 - A non-oriented 0.8 x 0.5 x 0.4 cm portion of yellow and tan soft tissue. Submitted in toto for frozen, B.

*FS/DX: SKELETAL MUSCLE AND VESSELS, NO TUMOR PRESENT.

(C) TEETH - Two teeth, gross only.

(D) LEFT FUNCTIONAL NECK DISSECTION, PARTIAL MANDIBULECTOMY, MAXILLECTOMY AND GLOSSECTOMY - Overall measurements of 14.0 x 8.0 x 6.5 cm. An ulcerated fungating and deeply infiltrating mass is identified measuring 4.5 x 3.8 x 4.0 cm. The lesion extends to the bone but is surrounded by uninvolved mucosa and soft tissue. Attached is a neck dissection with multiple involved lymph nodes. Representative sections are submitted.

SECTION CODE: _____ tumor and surrounding mucosa D6-D27; D28, submandibular gland; D29, five lymph nodes; D30, one lymph node; D31, one lymph node; D32, two lymph nodes; D33, one lymph node; D34, four lymph nodes; D35, two lymph nodes; D36, three lymph nodes; D37, two lymph nodes; D38, two lymph nodes; D39, two lymph nodes. AEN/mgd

*FS/DX: MODERATE DYSPLASIA; MARGINS ARE NEGATIVE FOR INVASIVE

Source: NCI Genomic Data Commons file e7a0ea37-1ede-4961-b062-03e8a8b966ef (TCGA-CV-6933.0EF36B6F-7335-4AD4-B41A-EB19DD07AE14.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).